Gene-level copy-number profile of tumor specimen TCGA-56-7580-01A from TCGA case TCGA-56-7580, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 84.2 years (30,740 days).
Specimen TCGA-56-7580-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7a0213fc-ba56-46dd-a2e3-9a1c69e678c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-7580-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bbf23686-c7eb-4107-ab9e-ba553f81fe24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 21,395; copy number 2: 33,802; copy number 3: 2,224; copy number 4: 2,161; copy number 5: 96; copy number 13: 2; copy number 14: 9; copy number 16: 4; copy number 17: 8; copy number 18: 4; copy number 20: 1; copy number 23: 10; copy number 28: 9; copy number 30: 1; copy number 31: 29; copy number 33: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-7580-01A-11D-2041-01): tumor purity 0.37, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,165,637–23,438,700, 53 genes (within-gene range 0–1): IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:38,620,474–38,662,717, 3 genes: FAM201A, YWHABP1, AL591543.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 181 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,709,295–170,396,835, 29 genes, copy number 31: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL.
- chr3:170,653,846–170,662,123, 2 genes, copy number 33 (within-gene range 4–33): AC026316.1, AC026316.3.
- chr3:171,058,414–171,460,408, 1 gene, copy number 23 (within-gene range 4–23): TNIK.
- chr3:171,439,526–171,938,715, 9 genes, copy number 23 (within-gene range 4–23): Y_RNA, AC092919.1, AC092919.2, RNU6-348P, AC008134.1, PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1.
- chr3:172,039,578–172,711,218, 13 genes, copy number 14–33 (within-gene range 4–33): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P.
- chr3:178,272,932–183,163,839, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:183,253,253–183,298,504, 2 genes, copy number 5: B3GNT5, RNA5SP151.
- chr8:125,859,721–126,292,788, 1 gene, copy number 18 (within-gene range 2–31): LINC00861.
- chr8:126,072,587–127,419,050, 12 genes, copy number 5–18 (within-gene range 1–28): KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P.
- chr8:127,072,694–127,227,541, 1 gene, copy number 13 (within-gene range 1–13): CASC19.
- chr8:127,289,817–127,482,139, 1 gene, copy number 28 (within-gene range 4–28): CASC8.
- chr8:127,322,183–128,187,101, 17 genes, copy number 17–30 (within-gene range 4–30): POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208.

Autosomal genes at a single copy (total copy number 1): 18,974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
